Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6170, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6170-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with a history of polyps and was under surveillance,
descending colon polyp biopsy showing invasive adenocarcinoma.

Specimens Submitted:

1: SP: Left colon; extended hemicolectomy

DIAGNOSIS:

1. SP: Left colon; extended hemicolectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Descending colon

Tumor Size:

Length is 3.5 cm

Width is 2.2 cm

Maximal thickness is 0.3 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Muscularis propria

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Tubular adenoma; number: 2

Non-Neoplastic Bowel:

** Continued on next page **

[page 2 of 3]
Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 12

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT2 (Tumor invades muscularis propria)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

[REDACTED]

1.) The specimen is received fresh, labeled "left hemicolectomy, extended left stitch marks proximal " and consists of a segment of colon measuring 49 cm in length with a circumference of 4.5 cm at the distal resected margin. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 4 cm in thickness. The specimen is opened to reveal a mass lesion measuring 3.5 cm in length and 2.2 cm in width. The mass is located 36 cm from the proximal margin and 4.3 cm from the distal margin. Sectioning shows that the tumor invades the muscularis propria. The depth of invasion is 0.5 cm grossly. The remaining mucosa shows two small polyps measuring 0.3 cm in greatest dimensions located 17 cm proximal to the tumor. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave

D - distal margin shave

T - tumor

P - polyps

RS -representative sections

LN - lymph nodes

BLN - bisected lymph nodes

** Continued on next page **

[page 3 of 3]
[REDACTED]

Summary of Sections:

Part 1: SP: Left colon; extended hemicolectomy

Block	Sect.	Site	PCs
1		D	1
7		LN	13
2		P	2
1		RS	1
4		T	4

** End of Report **

Source: NCI Genomic Data Commons file 94858094-89dc-4d92-b728-f0c6fa90bbcc (TCGA-CM-6170.319E200A-D0C5-47B3-9432-1EB1404233FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).